Somatic mutation profile of tumor specimen TCGA-A2-A4S1-01A (aliquot TCGA-A2-A4S1-01A-21D-A25Q-09) from TCGA case TCGA-A2-A4S1, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Metaplastic carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 66.7 years (24,353 days).
Specimen TCGA-A2-A4S1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 89f336ad-c95c-45bf-b482-f125f3fffdcd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A2-A4S1-10A (Blood Derived Normal), aliquot TCGA-A2-A4S1-10A-01D-A25Q-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/19f32793-f374-4c11-ade2-f9a7f202e732

The open-access MAF lists 69 somatic variants for this specimen: 60 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 54, Silent 8, Frame Shift Del 3, Nonsense Mutation 2, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.840A>C p.R280S | Missense Mutation (SNP) | VAF 19/43 reads (44%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.843); catalogued as rs1567547687, CM136794, COSV52678283, COSV52782181, COSV52801834, COSV53205654; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACAD8 | c.616C>T p.R206* | Nonsense Mutation (SNP) | VAF 21/129 reads (16%) | catalogued as rs369445365; called by muse, mutect2, varscan2
- ADAMTS1 | c.2556C>G p.I852M | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV53170347; called by muse, mutect2, varscan2
- ANKFN1 | c.310T>G p.S104A | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV59447375; called by muse, mutect2, varscan2
- ARHGEF28 | c.3787G>A p.D1263N | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); catalogued as COSV55256271; called by mutect2, varscan2
- C9orf85 | c.207G>C p.K69N | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.903); catalogued as rs1327558413, COSV58254331; called by muse, mutect2, varscan2
- CASK | c.527C>G p.A176G | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.034); catalogued as COSV59366649; called by muse, mutect2, varscan2
- CDH23 | c.1091G>C p.G364A | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as COSV54934267; called by muse, mutect2, varscan2
- CEP70 | c.1436T>A p.V479E | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99388706; called by muse, mutect2
- CETP | c.461G>A p.R154Q | Missense Mutation (SNP) | VAF 66/139 reads (47%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs184615182, CM140763, COSV52362586; called by muse, mutect2, varscan2
- CYP1A2 | c.94A>G p.R32G | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.209); catalogued as COSV100673835; called by muse, mutect2
- CYP2C19 | c.147T>A p.D49E | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.045); catalogued as COSV64907738; called by muse, mutect2, varscan2
- DLG1 | c.301C>A p.L101I | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.049); catalogued as COSV58382908; called by muse, mutect2
- DTWD2 | c.850C>T p.R284C | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as rs200315964, COSV58366531; called by muse, mutect2
- EIF3CL | c.972G>C p.E324D | Missense Mutation (SNP) | VAF 14/191 reads (7%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.717); catalogued as COSV101086001; called by muse, mutect2
- EXOC6B | c.1918G>A p.D640N | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.992); catalogued as COSV55555247; called by muse, mutect2, varscan2
- FER1L6 | c.2960C>T p.P987L | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs765039191, COSV67549898; called by muse, mutect2, varscan2
- FEZF2 | c.1153G>C p.G385R | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51862860, COSV51862959; called by muse, mutect2, varscan2
- FUNDC1 | c.349G>T p.A117S | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.56); PolyPhen benign (0.076); catalogued as COSV65181449; called by muse, mutect2, varscan2
- GFPT1 | c.1903G>T p.V635L (on ENST00000357308 / NM_001244710.2; = p.V617L on NM_002056.4) | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.101); catalogued as COSV61948031; called by muse, mutect2, varscan2
- GTPBP3 | c.104C>A p.T35N | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV50177191; called by muse, mutect2, varscan2
- GUCA1C | c.620A>G p.K207R | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as COSV53753170; called by muse, mutect2, varscan2
- HOOK3 | c.1086C>G p.N362K | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.793); catalogued as rs147428323, COSV56882432; called by muse, mutect2, varscan2
- IGSF1 | c.3159C>A p.S1053R | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV63837483; called by muse, mutect2, varscan2
- IL6 | c.133C>A p.Q45K | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.033); catalogued as COSV51732726; called by muse, mutect2, varscan2
- ITGB6 | c.1727G>T p.C576F | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51793855; called by muse, mutect2, varscan2
- IZUMO4 | c.272T>G p.L91R | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100642353; called by muse, mutect2
- KDR | c.983C>A p.P328H | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs767143286, COSV55765066; called by muse, mutect2, varscan2
- KDR | c.583G>T p.A195S | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.824); catalogued as COSV55765077; called by muse, mutect2, varscan2
- LGR4 | c.1817C>T p.A606V | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV64864348; called by muse, mutect2, varscan2
- LHX5 | c.149del p.L50Pfs*71 | Frame Shift Del (DEL) | VAF 8/59 reads (14%) | catalogued as COSV55662803; called by mutect2, pindel, varscan2
- LRP1B | c.2155A>T p.I719F | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV67220079; called by muse, mutect2, varscan2
- MAGED1 | c.2240C>T p.P747L | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.827); catalogued as COSV58515258; called by muse, mutect2, varscan2
- MTR | c.3481G>A p.A1161T | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs866499126, COSV63964459, COSV63964463; called by muse, mutect2
- NCOR2 | c.6898G>T p.E2300* | Nonsense Mutation (SNP) | VAF 11/62 reads (18%) | catalogued as COSV62298060; called by muse, mutect2, varscan2
- NLRP5 | c.3155C>T p.A1052V | Missense Mutation (SNP) | VAF 35/65 reads (54%) | SIFT tolerated (0.11); PolyPhen benign (0.079); catalogued as rs778328871, COSV66764528; called by muse, mutect2, varscan2
- PCDH11X | c.3064C>A p.P1022T | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.205); catalogued as COSV53465962; called by muse, mutect2, varscan2
- PITPNB | c.10A>T p.I4F | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.464); catalogued as COSV58061338; called by muse, mutect2, varscan2
- POMT2 | c.1070C>T p.S357F | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55071207; called by muse, mutect2, varscan2
- RASGRP4 | c.328A>C p.T110P | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated (0.43); PolyPhen benign (0.046); catalogued as COSV53095430; called by muse, mutect2, varscan2
- RBMS3 | c.812G>C p.S271T | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.109); catalogued as COSV56144956; called by muse, mutect2, varscan2
- RIMS3 | c.133C>T p.R45W | Missense Mutation (SNP) | VAF 35/72 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as COSV65504413, COSV65504453; called by muse, mutect2, varscan2
- SETD5 | c.572C>G p.S191C | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56710950; called by muse, mutect2, varscan2
- SETX | c.7568C>A p.T2523N | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.188); catalogued as COSV99808502; called by muse, mutect2
- SLC25A4 | c.367G>A p.A123T | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.801); catalogued as rs1312613444, COSV55668956; called by muse, mutect2, varscan2
- SLIT2 | c.1507G>T p.D503Y | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs763158714, COSV56568329, COSV56572530; called by muse, mutect2, varscan2
- SOX8 | c.752C>T p.P251L | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs755219338, COSV53509368; called by muse, mutect2, varscan2
- SPATA31D1 | c.3742G>C p.D1248H | Missense Mutation (SNP) | VAF 42/91 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.172); catalogued as COSV100782469, COSV61195726; called by muse, mutect2, varscan2
- SSH2 | c.262G>T p.D88Y | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52172385, COSV52183859; called by muse, mutect2, varscan2
- TC2N | c.855+1G>T p.X285_splice | Splice Site (SNP) | VAF 5/43 reads (12%) | catalogued as COSV61746961; called by muse, mutect2, varscan2
- TEX47 | c.677C>T p.P226L | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1476655610, COSV51878944; called by muse, mutect2, varscan2
- TMEM132D | c.1534A>G p.S512G | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.036); catalogued as COSV67160393; called by muse, mutect2, varscan2
- TP53BP1 | c.616A>T p.R206W | Missense Mutation (SNP) | VAF 43/189 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.43); catalogued as COSV55501232; called by muse, mutect2, varscan2
- TRAF6 | c.1174C>T p.R392C | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV61922493; called by muse, mutect2, varscan2
- TRIM21 | c.1307G>C p.C436S | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV54344199; called by muse, mutect2, varscan2
- TSPAN5 | c.530G>T p.R177L | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.839); catalogued as COSV59876017; called by muse, mutect2, varscan2
- GPR42 | c.44G>T p.W15L | Missense Mutation (SNP) | VAF 3/58 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.121); called by muse, mutect2
- IGHV3-35 | c.252G>C p.K84N | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- NF1 | c.8092_8098del p.Y2698Hfs*39 (on ENST00000358273 / NM_001042492.3; = p.Y2677Hfs*39 on NM_000267.3) | Frame Shift Del (DEL) | VAF 16/38 reads (42%) | called by mutect2, pindel, varscan2
- OR4S1 | c.724_731del p.V242Cfs*22 | Frame Shift Del (DEL) | VAF 19/90 reads (21%) | called by mutect2, pindel, varscan2
- ADM | c.261C>G p.A87= | Silent (SNP) | VAF 8/53 reads (15%) | catalogued as rs767028428, COSV53403100; called by mutect2, varscan2
- GPRIN2 | c.642G>A p.E214= | Silent (SNP) | VAF 12/80 reads (15%) | catalogued as COSV65401014; called by muse, mutect2
- GREB1 | c.918C>A p.S306= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as COSV52187061; called by muse, mutect2, varscan2
- OR5M10 | c.282C>T p.Y94= | Silent (SNP) | VAF 18/47 reads (38%) | catalogued as rs375793121; called by muse, mutect2, varscan2
- RFX6 | c.630A>G p.G210= | Silent (SNP) | VAF 6/94 reads (6%) | catalogued as COSV100262956; called by muse, mutect2
- TRAPPC9 | c.2709G>A p.Q903= | Silent (SNP) | VAF 3/45 reads (7%) | catalogued as rs1563669113; called by muse, mutect2
- XRN1 | c.1599G>A p.L533= | Silent (SNP) | VAF 14/78 reads (18%) | catalogued as COSV53811751; called by muse, mutect2, varscan2
- ZNF107 | c.780T>C p.T260= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as COSV61328659; called by muse, mutect2, varscan2
- CADM3 | c.89-2082G>T | Intron (SNP) | VAF 14/74 reads (19%) | catalogued as COSV100930232; called by muse, mutect2, varscan2
